Somatic mutation profile of tumor specimen TARGET-10-PARBXX-09A (aliquot TARGET-10-PARBXX-09A-01D) from TARGET case TARGET-10-PARBXX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,035 days).
Specimen TARGET-10-PARBXX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d45fb853-c170-407f-8694-125b5bc86a07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBXX-10A (Blood Derived Normal), aliquot TARGET-10-PARBXX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7098bdf4-2f21-4cf9-94cb-24a68fd4ac29

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Silent 2, Splice Region 1, Intron 1, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CLMN | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100111904; called by muse, mutect2, varscan2
- GPR179 | c.2654G>A p.R885Q (on ENST00000621958; = p.R884Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as rs747930627; called by muse, mutect2, varscan2
- HCFC2 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV57558155; called by muse, mutect2, varscan2
- HID1 | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60913992; called by muse, mutect2
- OR2L8 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 20/187 reads (11%) | catalogued as rs772728010, COSV61728124; called by muse, mutect2, varscan2
- ADGRL3 | c.2404C>A p.Q802K (on ENST00000506720 / NM_001322402.2; = p.Q734K on NM_015236.6) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); called by muse, mutect2
- DSP | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, varscan2
- KMT2D | c.2254_2255insG p.L752Rfs*6 | Frame Shift Ins (INS) | VAF 39/115 reads (34%) | called by mutect2, pindel, varscan2
- MOV10L1 | c.1009G>T p.V337F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PFKFB4 | c.988-6C>T | Splice Region (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- PIEZO1 | c.4061T>G p.M1354R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC7A4 | c.380T>A p.I127N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- STAB1 | c.3955G>T p.D1319Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.862); called by muse, varscan2
- COL11A1 | c.468T>G p.T156= | Silent (SNP) | VAF 49/128 reads (38%) | called by muse, mutect2, varscan2
- SEZ6 | c.1182T>C p.H394= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1454639841; called by muse, mutect2
- NUMA1 | c.1119+173_1119+179delinsAACTTAT | Intron (ONP) | VAF 7/69 reads (10%) | called by pindel, varscan2*
- RNU6-845P | chr16:46559959 A>T | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- TRARG1 | c.*81G>T | 3'UTR (SNP) | VAF 10/12 reads (83%) | called by mutect2, varscan2
